Somatic mutation profile of tumor specimen TCGA-DD-AADG-01A (aliquot TCGA-DD-AADG-01A-11D-A40R-10) from TCGA case TCGA-DD-AADG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 70.9 years (25,887 days).
Specimen TCGA-DD-AADG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a4a0297-bc6c-4a32-984d-bc5b7f04c1a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADG-10A (Blood Derived Normal), aliquot TCGA-DD-AADG-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a6c29da-0fe4-4e92-9cae-efaea61919f9

The open-access MAF lists 180 somatic variants for this specimen: 140 protein-altering or splice-affecting, 35 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 35, Nonsense Mutation 8, Frame Shift Del 7, Splice Site 4, In Frame Del 3, Intron 2, Frame Shift Ins 1, In Frame Ins 1, 3'UTR 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 42/134 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCA13 | c.5378T>C p.I1793T | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1437094633, COSV101330142; called by muse, mutect2, varscan2
- AKAP11 | c.1523A>G p.H508R | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99214235; called by muse, mutect2
- AMBN | c.347T>C p.L116S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV100534454; called by muse, mutect2, varscan2
- AMER1 | c.520A>G p.S174G | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100366873, COSV100367034; called by muse, mutect2, varscan2
- ANXA13 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as rs1375721396, COSV99146655; called by muse, mutect2, varscan2
- ANXA13 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.87); catalogued as COSV99146663; called by muse, mutect2, varscan2
- APOB | c.11171A>G p.K3724R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV99267224; called by muse, mutect2, varscan2
- ARHGEF4 | c.1502T>A p.I501N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100388530; called by muse, mutect2, varscan2
- ATF7IP | c.1037A>C p.D346A | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV99662012; called by muse, mutect2, varscan2
- ATP13A1 | c.3278A>C p.E1093A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99179502; called by muse, mutect2, varscan2
- ATP7A | c.1545A>T p.G515= | Splice Region (SNP) | VAF 67/79 reads (85%) | catalogued as COSV100431446; called by muse, mutect2, varscan2
- ATRNL1 | c.2689T>C p.S897P | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as COSV100372356; called by muse, mutect2, varscan2
- C1orf158 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as COSV55346815, COSV55347143, COSV99847419; called by muse, mutect2, varscan2
- CAMTA1 | c.3183G>C p.K1061N | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV100351950; called by muse, mutect2
- CBL | c.2555C>T p.T852I | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV99876799; called by muse, mutect2
- CEP170B | c.1706G>A p.G569E (on ENST00000453495; = p.G498E on NM_015005.3) | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038904275, COSV101371578; called by muse, mutect2, varscan2
- CHST14 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 226/702 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1176654221, COSV60379080; called by muse, mutect2, varscan2
- CKAP5 | c.5573A>G p.K1858R (on ENST00000529230 / NM_001008938.4; = p.K1798R on NM_014756.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as COSV100371262; called by muse, mutect2
- CNGA3 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM014539, COSV55624106, COSV99737274; called by muse, mutect2, varscan2
- COL1A2 | c.3475C>G p.P1159A | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99800689; called by muse, mutect2, varscan2
- COL5A3 | c.2460+1G>A p.X820_splice | Splice Site (SNP) | VAF 42/108 reads (39%) | catalogued as COSV99319524; called by muse, mutect2, varscan2
- CSDE1 | c.1735G>A p.V579M (on ENST00000358528 / NM_001007553.3; = p.V548M on NM_007158.6) | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99795728; called by muse, mutect2, varscan2
- CST9L | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV65408348; called by muse, mutect2, varscan2
- CYP4F3 | c.500T>C p.F167S | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99658557; called by muse, mutect2
- DCDC1 | c.4433T>G p.L1478R (on ENST00000597505 / NM_001367979.1; = p.L585R on NM_020869.3) | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100338670; called by muse, mutect2, varscan2
- DMD | c.610A>T p.R204* | Nonsense Mutation (SNP) | VAF 35/59 reads (59%) | catalogued as COSV99925038; called by muse, mutect2, varscan2
- DSC1 | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 42/107 reads (39%) | catalogued as COSV57151137; called by muse, mutect2, varscan2
- EIF3E | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99623410; called by muse, mutect2
- EPB41L2 | c.1345T>G p.S449A | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100441240; called by muse, mutect2, varscan2
- EPPIN | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100323348; called by muse, mutect2, varscan2
- FANCM | c.5255A>G p.N1752S | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99951489; called by muse, mutect2, varscan2
- FASN | c.7114G>C p.V2372L | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100148196; called by muse, mutect2, varscan2
- FGF12 | c.200-1G>A p.X67_splice (on ENST00000454309 / NM_021032.5; = p.X5_splice on NM_004113.6) | Splice Site (SNP) | VAF 47/117 reads (40%) | catalogued as COSV99283085; called by muse, mutect2, varscan2
- FOXE3 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV100624044; called by muse, mutect2, varscan2
- FTMT | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV100360425, COSV58420402; called by muse, mutect2, varscan2
- GABRB1 | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99782960; called by muse, mutect2
- GALNTL6 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72490507; called by muse, mutect2
- GIGYF2 | c.1826G>T p.R609L | Missense Mutation (SNP) | VAF 118/278 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV101004579, COSV65247095; called by muse, mutect2, varscan2
- GOPC | c.944T>G p.I315S | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50002084, COSV99271252; called by muse, mutect2
- GPR63 | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100013525; called by muse, mutect2, varscan2
- HEATR5B | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.109); catalogued as COSV99250038; called by muse, mutect2
- HOXD4 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752396313, COSV60459621, COSV60460364; called by muse, mutect2, varscan2
- HTT | c.1636A>G p.M546V | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs781353727, COSV100751126; called by muse, mutect2, varscan2
- ICE2 | c.875A>G p.N292S | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs201247512, COSV99831744; called by muse, mutect2, varscan2
- IGHV4-59 | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.045); catalogued as rs782087510; called by muse, mutect2
- IL12A | c.664T>A p.F222I | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.262); catalogued as COSV99975846; called by muse, mutect2
- ITPR1 | c.7415A>G p.D2472G (on ENST00000354582; = p.D2417G on NM_002222.7) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV100232702; called by muse, mutect2, varscan2
- KCNJ13 | c.706T>A p.F236I | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV99289380; called by muse, mutect2, varscan2
- KCNN2 | c.385G>T p.E129* (on ENST00000264773; = p.E341* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | catalogued as COSV99300470; called by muse, mutect2, varscan2
- KCTD18 | c.751C>A p.P251T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100728936, COSV63344334; called by muse, mutect2, varscan2
- KDELR2 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99330620, COSV99330709; called by muse, mutect2, varscan2
- KMT2B | c.3662G>T p.C1221F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99720373; called by muse, mutect2, varscan2
- L3MBTL2 | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99346094; called by muse, mutect2, varscan2
- LIN54 | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.14); catalogued as COSV100464900; called by muse, mutect2, varscan2
- LUC7L3 | c.194A>T p.N65I | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV99537104; called by muse, mutect2, varscan2
- LYNX1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs759423658, COSV100235753; called by muse, mutect2, varscan2
- MAGEA1 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV100756671; called by muse, mutect2
- MDH1B | c.154T>A p.C52S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100982262; called by muse, mutect2, varscan2
- METTL25 | c.668A>G p.H223R | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV99942609; called by muse, mutect2, varscan2
- MGAM | c.1978G>T p.G660C | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527697; called by muse, mutect2, varscan2
- MGAM | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527698; called by muse, mutect2, varscan2
- MLH3 | c.3701A>T p.E1234V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99470578; called by muse, mutect2, varscan2
- MROH5 | c.1476G>T p.R492S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as COSV101436096, COSV71302131; called by muse, mutect2, varscan2
- MTBP | c.733A>T p.I245L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV100012466; called by muse, mutect2, varscan2
- MUSK | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs776795823, COSV51877981; called by muse, mutect2, varscan2
- MYH2 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99820710; called by muse, mutect2, varscan2
- NAA25 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV99927917; called by muse, mutect2, varscan2
- NAV3 | c.4417G>A p.G1473R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99894295; called by muse, mutect2, varscan2
- NFATC1 | c.1586C>A p.A529D | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99502297; called by muse, mutect2, varscan2
- NLRP3 | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100276482; called by muse, mutect2, varscan2
- NOCT | c.637C>A p.Q213K | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as COSV99763934; called by muse, mutect2, varscan2
- NOP9 | c.1793A>T p.H598L | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99351073; called by muse, mutect2, varscan2
- NUDT12 | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100048304; called by muse, mutect2, varscan2
- OR12D3 | c.729T>A p.H243Q | Missense Mutation (SNP) | VAF 8/233 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011415; called by muse, mutect2
- OR4N5 | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV100374187; called by muse, mutect2, varscan2
- OR52R1 | c.833T>A p.L278Q | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100617777; called by muse, mutect2, varscan2
- P2RX1 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV99844894; called by muse, mutect2, varscan2
- PATJ | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100334756; called by muse, mutect2
- PCLO | c.13318G>T p.E4440* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100436277; called by muse, mutect2, varscan2
- PHC2 | c.968T>C p.I323T | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99931298; called by muse, mutect2
- PITX2 | c.515C>A p.P172Q (on ENST00000354925 / NM_001204397.1; = p.P179Q on NM_000325.6) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100146424; called by muse, mutect2, varscan2
- POM121 | c.3040A>G p.M1014V (on ENST00000434423; = p.M749V on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99989015; called by muse, mutect2, varscan2
- PRDM16 | c.2851T>A p.Y951N | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99578259; called by muse, mutect2
- PRELP | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs370346520; called by muse, mutect2, varscan2
- PRKAG3 | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99292081; called by muse, mutect2
- PSMB7 | c.683T>G p.F228C | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV99413033; called by muse, mutect2, varscan2
- RANBP3 | c.821A>T p.N274I (on ENST00000340578 / NM_007322.3; = p.N269I on NM_003624.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV99222459; called by muse, mutect2, varscan2
- RASSF5 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV100795232; called by muse, mutect2
- RBM27 | c.1888A>G p.I630V | Missense Mutation (SNP) | VAF 23/429 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV99506502; called by muse, mutect2
- RGS3 | c.657G>T p.L219F (on ENST00000350696 / NM_001282923.2; = p.L107F on NM_017790.4) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100465753; called by muse, mutect2, varscan2
- RP1 | c.2840G>T p.C947F | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.243); catalogued as COSV99608464; called by muse, mutect2
- RPTN | c.1323G>T p.Q441H | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100285672; called by muse, mutect2, varscan2
- RPTOR | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100156970; called by muse, mutect2, varscan2
- SEMA6D | c.2386C>T p.H796Y (on ENST00000316364 / NM_153618.2; = p.H734Y on NM_020858.2) | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100317414; called by muse, mutect2
- SFXN2 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV100882762; called by muse, mutect2, varscan2
- SLC29A3 | c.548G>C p.S183T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV100928576; called by muse, mutect2, varscan2
- SLC30A5 | c.811A>G p.I271V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV101173638; called by muse, mutect2, varscan2
- SLC38A2 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs746626410, COSV99874059; called by muse, mutect2, varscan2
- SLCO1C1 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.05); catalogued as COSV56879975, COSV99859733; called by muse, mutect2, varscan2
- SLIRP | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV53173894, COSV53173921, COSV53174466; called by muse, mutect2, varscan2
- SLITRK4 | c.2423A>T p.K808M | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100567461; called by muse, mutect2
- SLITRK4 | c.2421G>C p.R807S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as rs1251514394, COSV100567462, COSV62025592; called by muse, mutect2
- SMCR8 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100329250; called by muse, mutect2, varscan2
- SORBS2 | c.1676A>G p.N559S | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99512223; called by muse, mutect2, varscan2
- STIP1 | c.662A>G p.N221S | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV100534947; called by muse, mutect2, varscan2
- SULT4A1 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99970682; called by muse, mutect2, varscan2
- TBX6 | c.1309T>G p.*437Gext*81 | Nonstop Mutation (SNP) | VAF 32/156 reads (21%) | catalogued as COSV99661759; called by muse, varscan2
- TEKT4 | c.1177C>A p.L393I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99726631; called by muse, mutect2, varscan2
- TFCP2 | c.357A>G p.I119M | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV99227800; called by muse, mutect2, varscan2
- TMPRSS15 | c.881-2A>T p.X294_splice | Splice Site (SNP) | VAF 22/303 reads (7%) | catalogued as COSV99518908; called by muse, mutect2
- TMPRSS3 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV52304183; called by muse, mutect2, varscan2
- TPO | c.2056C>A p.L686M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100221813; called by muse, mutect2, varscan2
- TRIM13 | c.382T>C p.F128L | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.191); catalogued as COSV100078510; called by muse, mutect2
- TRIP10 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | catalogued as rs1285236791, COSV57570607, COSV57575138; called by muse, mutect2, varscan2
- TRPC1 | c.1934T>A p.L645H (on ENST00000476941 / NM_001251845.2; = p.L611H on NM_003304.4) | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99859213; called by muse, mutect2, varscan2
- TWIST1 | c.571A>G p.R191G | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99642970, COSV99643154; called by muse, mutect2, varscan2
- USP24 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.446); catalogued as rs374277857; called by muse, mutect2, varscan2
- USP40 | c.2970G>T p.E990D | Missense Mutation (SNP) | VAF 151/376 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV99296984; called by muse, mutect2, varscan2
- VEZF1 | c.299A>C p.K100T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99365830; called by muse, mutect2, varscan2
- ZFP36L2 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99144108; called by muse, mutect2, varscan2
- ZFP91 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100284694; called by muse, mutect2, varscan2
- ZNF831 | c.4280T>C p.L1427P | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100926182; called by muse, mutect2, varscan2
- ZSCAN22 | c.895A>T p.S299C | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100308459; called by muse, mutect2, varscan2
- ALB | c.1277_1289+1del p.X426_splice | Splice Site (DEL) | VAF 68/190 reads (36%) | called by mutect2, pindel, varscan2
- ANGPTL8 | c.105_116del p.T36_F39del | In Frame Del (DEL) | VAF 35/118 reads (30%) | called by mutect2, pindel, varscan2
- CCT8L2 | c.2_5del p.M1_?2 | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | called by mutect2, pindel, varscan2
- CDC5L | c.2361del p.R787Sfs*12 | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- CDKN2A | c.67_76del p.G23Rfs*27 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- COPS5 | c.611_643delinsGAC p.Q204_G215delinsRR | In Frame Del (DEL) | VAF 39/116 reads (34%) | called by pindel, varscan2*
- DAPK1 | c.83del p.K28Rfs*29 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | called by mutect2, pindel, varscan2
- EFCAB7 | c.1194_1195dup p.F399Yfs*17 | Frame Shift Ins (INS) | VAF 78/232 reads (34%) | called by mutect2, pindel, varscan2
- GPR146 | c.180del p.M61Cfs*63 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | called by mutect2, varscan2
- GPRIN1 | c.644del p.G215Efs*3 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | called by mutect2, pindel, varscan2
- IFIT5 | c.192del p.G65Afs*16 | Frame Shift Del (DEL) | VAF 48/165 reads (29%) | called by mutect2, pindel, varscan2
- IGHV3-16 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LSM8 | c.273_278del p.L91_S93delinsF | In Frame Del (DEL) | VAF 39/150 reads (26%) | called by mutect2, pindel, varscan2
- MIER1 | c.1319_1320insGAT p.D440delinsEI (on ENST00000355356 / NM_001077701.3; = p.D457delinsEI on NM_020948.4 and 2 other RefSeq transcripts) | In Frame Ins (INS) | VAF 86/185 reads (46%) | called by mutect2, pindel*, varscan2*
- NBPF9 | c.89A>T p.E30V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PCDH7 | c.2314T>A p.C772S | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BMPR2 | c.747G>A p.V249= | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as COSV101001609; called by muse, mutect2
- C22orf42 | c.582T>C p.L194= | Silent (SNP) | VAF 160/426 reads (38%) | catalogued as rs1300525420, COSV101173367; called by muse, mutect2, varscan2
- CCR5 | c.327T>C p.F109= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV99433603; called by muse, mutect2, varscan2
- CDK5RAP2 | c.618C>T p.H206= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs778174320, COSV62575935; called by muse, mutect2, varscan2
- CH25H | c.366C>A p.L122= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV100897384; called by muse, mutect2, varscan2
- CHST14 | c.252C>A p.R84= | Silent (SNP) | VAF 222/691 reads (32%) | catalogued as COSV100087048; called by muse, mutect2, varscan2
- CLN5 | c.96G>C p.L32= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV101080408; called by muse, mutect2
- COL14A1 | c.3957T>A p.V1319= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV99920237; called by muse, mutect2, varscan2
- DDX11 | c.120G>T p.G40= | Silent (SNP) | VAF 45/681 reads (7%) | catalogued as rs1390080169, COSV99300086; called by muse, mutect2
- DNAH7 | c.4423C>A p.R1475= | Silent (SNP) | VAF 66/179 reads (37%) | catalogued as COSV100416869; called by muse, mutect2, varscan2
- DSG3 | c.1902C>T p.A634= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV99934588; called by muse, mutect2, varscan2
- DYNC1LI2 | c.882C>T p.F294= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as rs866124799; called by muse, mutect2
- FRYL | c.8181G>A p.E2727= | Silent (SNP) | VAF 98/284 reads (35%) | catalogued as rs769705409, COSV99977770; called by muse, mutect2, varscan2
- FSCN2 | c.69C>T p.Y23= | Silent (SNP) | VAF 56/192 reads (29%) | catalogued as COSV100603322; called by mutect2, varscan2
- GCN1 | c.3027C>A p.I1009= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV100325839; called by muse, mutect2, varscan2
- GFOD1 | c.855G>C p.V285= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV101015192; called by muse, mutect2, varscan2
- GPR176 | c.1419G>A p.K473= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as rs1381642544, COSV100137417; called by muse, mutect2
- GRM6 | c.687G>A p.G229= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as rs752091831, COSV99179811; called by muse, mutect2, varscan2
- GRM8 | c.1872G>T p.V624= | Silent (SNP) | VAF 56/175 reads (32%) | catalogued as rs775112738, COSV100285098; called by muse, mutect2, varscan2
- HMCN1 | c.14055A>C p.A4685= | Silent (SNP) | VAF 9/162 reads (6%) | catalogued as COSV99634016; called by muse, mutect2
- IGSF1 | c.108T>C p.P36= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as COSV100812248; called by muse, mutect2, varscan2
- NEPRO | c.837A>G p.K279= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as COSV100075132; called by muse, mutect2, varscan2
- NPHP4 | c.339C>T p.V113= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as rs771576802, COSV100977100; called by muse, mutect2, varscan2
- NUP155 | c.3345A>G p.L1115= (on ENST00000231498 / NM_153485.3; = p.L1056= on NM_004298.4) | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99194222; called by muse, mutect2, varscan2
- OR11H4 | c.255C>G p.S85= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV100197587, COSV59560507; called by muse, mutect2
- OR6Q1 | c.240G>C p.V80= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as COSV100110373; called by muse, mutect2
- OXR1 | c.609T>G p.T203= (on ENST00000442977 / NM_001198532.1; = p.T202= on NM_018002.3) | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV100367630; called by muse, mutect2, varscan2
- PRAMEF19 | c.888G>A p.E296= | Silent (SNP) | VAF 31/454 reads (7%) | called by muse, mutect2
- PRDM9 | c.2262G>A p.G754= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as COSV99690974; called by muse, varscan2
- PRPF4B | c.1188C>T p.S396= | Silent (SNP) | VAF 27/221 reads (12%) | catalogued as rs751880533, COSV61785806; called by muse, mutect2, varscan2
- SIGLEC6 | c.1170C>A p.V390= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100585615; called by muse, mutect2, varscan2
- SIX6 | c.483C>A p.L161= | Silent (SNP) | VAF 91/254 reads (36%) | catalogued as COSV100576534, COSV59803481; called by muse, mutect2, varscan2
- SRGAP2 | c.306C>T p.L102= | Silent (SNP) | VAF 131/582 reads (23%) | called by muse, mutect2, varscan2
- TRIM24 | c.1488T>G p.P496= | Silent (SNP) | VAF 137/484 reads (28%) | catalogued as COSV100631163; called by muse, mutect2, varscan2
- TSHZ3 | c.1443T>C p.T481= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99552387; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1622C>T | 3'UTR (SNP) | VAF 63/160 reads (39%) | catalogued as COSV100247282; called by muse, mutect2, varscan2
- OR3A4P | n.776T>A | RNA (SNP) | VAF 41/66 reads (62%) | called by muse, mutect2, varscan2
- RBMS1 | c.901-933A>T | Intron (SNP) | VAF 7/127 reads (6%) | catalogued as COSV100816997, COSV62351047; called by muse, mutect2
- SPACA6 | chr19:51692844 G>T | 5'Flank (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- TCF7 | c.1149-24G>A | Intron (SNP) | VAF 32/136 reads (24%) | catalogued as COSV100390045, COSV100390113; called by muse, mutect2, varscan2
